FM case AD14038 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/62b05978-e1a5-4ab5-9b9c-c1c715beb8c4

Male, 49.2 years: diagnosis not reported by GDC of the biliary tract; primary biopsied or resected from the extrahepatic bile duct. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
